Somatic mutation profile of tumor specimen 0DI7TN from CCDI case PBBVLS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,355 days).
Specimen 0DI7TN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e642142-5330-4449-a8d5-e6d678394697.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b24a9a1e-7a23-46df-980d-357e91c8f649

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 591/1294 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH3A2 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 437/1495 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs372095991; called by muse, mutect2, varscan2
- ATR | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 527/1726 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV63386876; called by muse, mutect2, varscan2
- DOK6 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 374/906 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203760352; called by muse, mutect2, varscan2
- LATS2 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 46/1323 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV66873682; called by muse, mutect2
- MSRB1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 146/451 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs552092161; called by muse, varscan2
- OAS3 | c.2636C>T p.T879M | Missense Mutation (SNP) | VAF 344/1136 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.732); catalogued as rs550945075; called by muse, mutect2, varscan2
- PECAM1 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 71/1072 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as rs1288383955; called by muse, mutect2
- PLA2G4A | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 209/1216 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs143369014, COSV66552570; called by muse, varscan2
- PROX1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 711/1643 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54779066; called by muse, mutect2, varscan2
- SMARCA4 | c.3529G>A p.D1177N | Missense Mutation (SNP) | VAF 697/1257 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60789707; called by muse, mutect2, varscan2
- SPATA2L | c.941G>C p.R314P | Missense Mutation (SNP) | VAF 105/582 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV57048594; called by muse, mutect2, varscan2
- SULF1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 101/1206 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs144030540; called by muse, mutect2
- VCAN | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 447/1568 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV54102219; called by muse, mutect2, varscan2
- WAPL | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 98/1708 reads (6%) | catalogued as rs1291511350; called by muse, mutect2
- ZNF282 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 259/559 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.561); catalogued as rs963030838; called by muse, mutect2, varscan2
- ARID1A | c.4340_4343del p.P1447Qfs*33 | Frame Shift Del (DEL) | VAF 121/982 reads (12%) | called by mutect2, varscan2*
- CHD6 | c.4481G>A p.S1494N | Missense Mutation (SNP) | VAF 114/2060 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- DTD1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 84/1300 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- EMC2 | c.671G>T p.R224I | Missense Mutation (SNP) | VAF 610/1898 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by mutect2, varscan2
- FGF8 | c.698G>C p.R233P (on ENST00000344255 / NM_033164.4; = p.R215P on NM_006119.6) | Missense Mutation (SNP) | VAF 54/1034 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- JMJD1C | c.3665G>A p.G1222D | Missense Mutation (SNP) | VAF 579/1891 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MVK | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 108/992 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OPALIN | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 317/1043 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINA1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 106/683 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TOPBP1 | c.3242C>A p.A1081E | Missense Mutation (SNP) | VAF 100/1470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKRA2 | c.270G>A p.V90= | Silent (SNP) | VAF 548/1395 reads (39%) | called by muse, mutect2, varscan2
- CUL4B | c.2328A>G p.G776= | Silent (SNP) | VAF 320/795 reads (40%) | called by muse, mutect2, varscan2
- FASTKD3 | c.1113C>T p.V371= | Silent (SNP) | VAF 544/1525 reads (36%) | called by muse, mutect2, varscan2
- PCDHB10 | c.2085G>A p.A695= | Silent (SNP) | VAF 19/323 reads (6%) | catalogued as rs782285268; called by muse, mutect2
- PNMA8A | c.966C>G p.A322= | Silent (SNP) | VAF 46/522 reads (9%) | called by muse, mutect2
- PSEN2 | c.1242C>T p.P414= | Silent (SNP) | VAF 325/771 reads (42%) | catalogued as rs751025333, COSV100422733; called by muse, mutect2, varscan2
- IFRD2 | c.1078-49C>T | Intron (SNP) | VAF 42/106 reads (40%) | catalogued as rs375674476; called by muse, mutect2
- NDUFB11 | chrX:47144774 C>T | 5'Flank (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- RNMT | c.*2063T>G | 3'UTR (SNP) | VAF 40/1410 reads (3%) | called by muse, mutect2
